Somatic mutation profile of tumor specimen BA2566D (aliquot aq-BA2566D) from BEATAML1.0 case 2210, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.5 years (18,430 days).
Specimen BA2566D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d340d24a-e09f-46b5-a169-b7e22d1dfb39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2274D (Solid Tissue Normal), aliquot aq-BA2274D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f934af6-0ed5-4586-8070-072bd718c24a

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ROBO1 | c.4156G>A p.G1386R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV71393667; called by muse, mutect2, varscan2
- SMR3B | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV59229436; called by muse, mutect2, varscan2
- DUOX1 | c.3724G>T p.A1242S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by mutect2, varscan2
- FLNB | c.3281C>A p.T1094N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HTR4 | c.337T>C p.C113R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF786 | c.1698G>T p.S566= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- MYL3 | chr3:46833609 C>T | 3'Flank (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
